CCDI case PBCMDA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/efa60cb9-5529-4f60-8c72-c269f5e76d84

Demographics
Sex at birth: male; Race: white.

Biospecimens (3 samples)
- Sample 0DVKDK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVKDW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DVKED: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
